CCDI case PBCADR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e24c19a7-f14a-4c39-845f-881b40dc41e7

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,851 days).

Biospecimens (2 samples)
- Sample 0DM4X9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM4XN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
